Somatic mutation profile of tumor specimen TCGA-VP-A872-01A (aliquot TCGA-VP-A872-01A-11D-A34U-08) from TCGA case TCGA-VP-A872, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.5 years (22,098 days).
Specimen TCGA-VP-A872-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b1c2aa8-12d6-4ef8-a100-5177c7a89eeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A872-10A (Blood Derived Normal), aliquot TCGA-VP-A872-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0197e162-3032-488d-bbc7-620bb3faf89f

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Ins 3, RNA 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.4457C>T p.A1486V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs375389452; called by muse, mutect2, varscan2
- DGKB | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751382500, COSV51765781, COSV51780055; called by muse, mutect2, varscan2
- EMX1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037079323, COSV99252365; called by muse, mutect2, varscan2
- FAM217B | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100674409; called by muse, mutect2, varscan2
- HSPA8 | c.419C>A p.T140N | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as rs141156763, COSV99914214; called by muse, mutect2
- IGHV1-58 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs370108530; called by muse, mutect2, varscan2
- IVD | c.888G>A p.G296= (on ENST00000651168; = p.G293= on NM_002225.5 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99991375; called by muse, mutect2
- OR2T12 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as COSV100527807, COSV58776817; called by mutect2, varscan2
- POLQ | c.4289dup p.L1430Ffs*5 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | catalogued as rs755281591, COSV99951761; called by mutect2, varscan2
- POLR1B | c.173T>A p.V58E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99271027; called by muse, mutect2, varscan2
- PRPF40B | c.143C>T p.A48V (on ENST00000380281; = p.A42V on NM_012272.3) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs149751647; called by muse, mutect2, varscan2
- PTPN20 | c.1193C>T p.T398M (on ENST00000374339 / NM_001042357.4; = p.N214= on NM_015605.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/447 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782166075; called by muse, mutect2, varscan2
- RYR1 | c.4306G>A p.V1436M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200289457, COSV100614600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SET | c.409A>G p.I137V (on ENST00000372692 / NM_001374326.1; = p.I124V on NM_003011.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV100433027; called by mutect2, varscan2
- TNXB | c.1930G>A p.G644S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764261572, COSV64476493; called by muse, mutect2, varscan2
- TRIO | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100709923; called by muse, mutect2, varscan2
- CLSTN3 | c.2076dup p.T693Dfs*8 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- NLRP4 | c.1096del p.Q366Rfs*31 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- TCERG1 | c.1245_1246dup p.Q416Pfs*12 | Frame Shift Ins (INS) | VAF 47/197 reads (24%) | called by mutect2, pindel, varscan2
- ABCA7 | c.819C>T p.A273= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99565214; called by muse, mutect2, varscan2
- MOV10L1 | c.1371C>T p.R457= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs144983844; called by muse, mutect2, varscan2
- PCDHGA1 | c.2232C>T p.D744= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV65296209; called by muse, mutect2, varscan2
- TNC | c.828C>T p.G276= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs753044795, COSV100405026, COSV60788786; called by muse, mutect2, varscan2
- DCHS2 | n.7205A>T | RNA (SNP) | VAF 8/119 reads (7%) | catalogued as COSV100601132; called by muse, mutect2
